Gene-level copy-number profile of tumor specimen TCGA-33-4532-01A from TCGA case TCGA-33-4532, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.9 years (25,169 days).
Specimen TCGA-33-4532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.31dfca53-3810-401c-85e8-395934425a5c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-4532-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07b96bac-9fc9-4c50-86fb-48cfa27d5dcf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 112; copy number 1: 7,112; copy number 2: 39,374; copy number 3: 8,843; copy number 4: 2,641; copy number 5: 902; copy number 6: 347; copy number 7: 200; copy number 8: 103; copy number 9: 95; copy number 11: 15; copy number 12: 6; copy number 14: 20; copy number 16: 27; copy number 24: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-4532-01A-01D-1195-01): tumor purity 0.56, ploidy 5.54, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:4,317,388–4,503,392, 2 genes: AC027251.1, AC010941.1.
- chr13:18,467,172–21,061,586, 87 genes (broad region; genes not listed).
- chr13:26,557,683–26,905,861, 6 genes: WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1.
- chr13:32,877,431–33,350,630, 6 genes (within-gene range 0–2): LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS.
- chr13:63,667,681–63,844,125, 9 genes: LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1.
- chr13:82,778,208–83,102,335, 2 genes (within-gene range 0–2): AL445255.1, GYG1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,678 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:5,313,740–6,003,510, 10 genes, copy number 5: AC073143.1, AC107057.1, LINC01248, AC108025.1, SOX11, AC010729.2, AC010729.1, LINC01810, SILC1, MIR7158.
- chr2:58,427,799–59,063,766, 1 gene, copy number 5 (within-gene range 4–5): LINC01122.
- chr2:59,014,354–61,888,671, 59 genes, copy number 5 (within-gene range 4–5): AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3.
- chr3:162,486,541–169,939,175, 76 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:170,086,732–192,119,864, 378 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:194,402,672–198,222,513, 143 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:58,198–4,013,649, 93 genes, copy number 5 (broad region; genes not listed).
- chr5:35,429,064–36,725,195, 26 genes, copy number 12–14: U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3.
- chr12:40,978,744–41,932,592, 9 genes, copy number 6: AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1.
- chr12:45,050,901–45,103,107, 1 gene, copy number 7 (within-gene range 4–7): AC008127.1.
- chr12:45,117,771–49,019,235, 134 genes, copy number 5–11 (broad region; genes not listed).
- chr15:88,989,519–101,933,350, 326 genes, copy number 6–9 (broad region; genes not listed).
- chr19:22,555,261–22,925,547, 24 genes, copy number 8–9: RNU6-1179P, AC011467.5, GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2, ZNF492, AC024563.1, ZNF849P, RPL34P33, AC024563.2, VN1R87P, ZNF99, AC008626.2, AC008626.1, BNIP3P34, ZNF723, BNIP3P35, VN1R88P, AC022145.1, AC022145.2.
- chr19:37,506,939–38,949,855, 67 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:5,292,388–17,569,220, 159 genes, copy number 6–7 (broad region; genes not listed).
- chr20:17,576,206–17,576,510, 1 gene, copy number 6: RN7SKP69.
- chr20:50,510,321–52,670,578, 37 genes, copy number 6 (within-gene range 4–6): PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4.
- chr22:25,959,074–27,041,494, 34 genes, copy number 6: Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3, LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5.
- chr22:29,554,808–31,750,140, 99 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr22:31,757,202–31,757,498, 1 gene, copy number 8: RN7SL20P.

Autosomal genes at a single copy (total copy number 1): 6,085. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
